Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B0GH, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B0GH-TTP1-A (Primary Tumor).

[page 1 of 15]
Surgical Pathology Report

Patient Name: [REDACTED]
Date of Procedure: [REDACTED] +20
Sex: Male
Referring Physician: [REDACTED]

Accession No: [REDACTED]
Date Received: [REDACTED] +21
Date of Birth: [REDACTED]
Service: [REDACTED]
Hospital No: [REDACTED]

Clinical History:

-30

The patient is a 51-year-old male with a sudden onset of difficulty speaking on [REDACTED]. The patient has had grand mal seizures. A CT scan of the head showed a low density area in the left posterior-superior temporal area.

Gross Description:

Received fresh for frozen section diagnosis, labeled with the patient's name and hospital number and designated "temporal tumor," are multiple fragments of soft brown-tan tissue that measure 1.5 x .7 x .4 cm in aggregate. Half of the specimen is used for frozen section diagnosis, then transferred to cassette [REDACTED] for permanent section processing, while the remaining tissue is placed entirely in cassette [REDACTED].

Received in formalin, labeled with the patient's name and hospital number and designated "left temporal tumor," are multiple loose fragments of soft brown-tan tissue. In addition, there is a nylon sac within the specimen that upon opening contains additional fragments of soft brown-tan tissue. The specimen measures 8.0 x 4.0 x 2.0 cm in aggregate. The specimen is submitted entirely in cassettes [REDACTED].

Frozen Section Diagnosis:

[REDACTED] Temporal tumor, stereotactic biopsy: Glioblastoma multiforme [REDACTED]

The following special procedures were performed on this case:

Note: The above list of special procedures does not reflect test results. Please refer to Microscopic Description or Diagnosis, as shown below, for the interpretation of the results of special stains.

Microscopic Diagnosis:

Brain mass, left temporal lobe, resection:

- Glioblastoma multiforme (WHO grade IV)

Interpreted by:

[REDACTED]

[REDACTED]

"I certify that (1) all services on this form were rendered and are hereby approved for billing; (2) the medical record has been documented for these services, and (3) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines."

[page 2 of 15]
Surgical Pathology Report

Patient Name: [REDACTED]
Date of Procedure: [REDACTED] +20
Sex: Male
Referring Physician: [REDACTED]

Accession No: [REDACTED]
Date Received: [REDACTED] +21
Date of Birth: [REDACTED]
Service: [REDACTED]
Hospital No: [REDACTED]

Addendum ([REDACTED] +930

+23

This addendum supersedes the original report issued [REDACTED]. This report includes results of 1p,19q and EGFR analysis performed at [REDACTED] in the comment below. The diagnosis remains unchanged.

-30

Clinical History:

The patient is a 51-year-old male with a sudden onset of difficulty speaking on [REDACTED]. The patient has had grand mal seizures. A CT scan of the head showed a low density area in the left posterior-superior temporal area.

Gross Description:

Received fresh for frozen section diagnosis, labeled with the patient's name and hospital number and designated "temporal tumor," are multiple fragments of soft brown-tan tissue that measure 1.5 x .7 x .4 cm in aggregate. Half of the specimen is used for frozen section diagnosis, then transferred to cassette ([REDACTED]) for permanent section processing, while the remaining tissue is placed entirely in cassette ([REDACTED]).

Received in formalin, labeled with the patient's name and hospital number and designated "left temporal tumor," are multiple loose fragments of soft brown-tan tissue. In addition, there is a nylon sac within the specimen that upon opening contains additional fragments of soft brown-tan tissue. The specimen measures 8.0 x 4.0 x 2.0 cm in aggregate. The specimen is submitted entirely in cassettes ([REDACTED]).

Frozen Section Diagnosis:

[REDACTED] Temporal tumor, stereotactic biopsy: Glioblastoma multiforme ([REDACTED])

The following special procedures were performed on this case: ^p53 +
^MIB-1 +

Note: The above list of special procedures does not reflect test results. Please refer to Microscopic Description or Diagnosis, as shown below, for the interpretation of the results of special stains.

Microscopic Diagnosis:

Brain mass, left temporal lobe, resection:

- Glioblastoma multiforme (WHO grade IV)
- **Positive for high level amplification of EGFR (7p12)**
- **Negative for deletion of 1p36 sequences (ratio 1p36:1q25=1.00)**
- **Negative for deletion of 19q13 sequences (ratio 19q13:19p13=0.99)**

+930

Addendum Comment ([REDACTED]): At the request of the clinicians additional testing is performed to better assess any possible unusual features in this patient (who has enjoyed survival over 2 years. MIB-1 cell cycle labeling index is high, exceeding 20%, TP53 immunostaining is seen in 5-10% of nuclei but if focally higher.

[page 3 of 15]
Surgical Pathology Report

Patient Name: [REDACTED]

Date of Procedure: [REDACTED] +20

Sex: Male

Referring Physician: [REDACTED]

Accession No: [REDACTED]

Date Received: [REDACTED] +21

Date of Birth: [REDACTED]

Service: [REDACTED]

Hospital No: [REDACTED]

Two dual color chromosome enumeration assays were performed to assess deletion of 1p36 relative to a control probe for 1q25, and deletion of 19q13 relative to a control probe for 19p13. The ratios for these probes are listed above. A normal ratio is approximately 1.0. Any ratio < 0.80 is consistent with deletion of the region of interest. There is no evidence of deletion of either sequence with this method.

A dual color chromosome enumeration assay for interphase cells was performed using a chromosome 7p12 (EGFR)-specific DNA probe and an alpha satellite probe for chromosome 7 centromere. The section contained a cell population with > 10 copies of EGFR in a signal pattern consistent with the presence of double minutes. Gain of chromosome 7 centromeric sequences was not observed.

Amplification of the EGFR gene is a common finding in high grade astrocytic tumors, in particular, glioblastoma multiforme. It is usually considered to be a poor prognostic indicator. Gain of chromosome 7 is another recurring finding in GBM.

"I certify that (1) all services on this form were rendered and are [REDACTED] ented for these services, and (3) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines."

[page 4 of 15]
MRI Report

+20

SEX: M

Patient Location:

Status: I

Accession Number:

MAGNETIC RESONANCE IMAGING

Physician:

Requested

Observatio

+20

Diagnosis: SURGERY PLANNING STUDY

History:

GLIOMA. RAPIDLY GROWING LESION.

DATE OF DICTATION: +20

HISTORY: Rapidly growing lesion. Surgical planning.
Probable glioma.

MRI OF THE BRAIN WITH CONTRAST:

TECHNIQUE: The study consists of 3 x 3 mm axial T1-weighted images with contrast and sagittal T1-weighted images with contrast.

+18

No previous films are available for comparison. However, there is a PET report available from [REDACTED] which describes a ring of hypermetabolic activity that compares to prior MR scans where a lesion in the left temporoparietal region measured 21 x 20 mm and had since grown.

On the current study, there is a large lesion present within the left posterior temporal region extending into the frontoparietal region. It has irregular, thick-walled peripheral enhancement and measures approximately 3.8 x 4.1 cm in AP x width dimension. This is larger than the measurements given on that prior MR scan as referenced in the PET report. There is surrounding hypoattenuation seen on the T1-weighted images extending further anterior into the temporal lobe as well as medially into the left lateral ventricle and also further into the parietal and posterior frontal regions. The left lateral ventricle is moderately compressed and there is a moderate shift of midline structures toward the right. The left temporal horn is moderately large, which is likely related to it being "trapped" due to the adjacent lesion compressing the left lateral ventricle. The left lateral ventricle trigone and temporal horn posterior to this are markedly compressed. The central portion of the lesion is not enhancing, and of decreased signal intensity on the T1-weighted images. There is also additional swelling with compression of the underlying sulci. Small areas of enhancement around the periphery of the lesion are likely related

[page 5 of 15]
[REDACTED]

to vessel. No additional enhancing lesions are identified.

Within both maxillary sinuses, there are lesions which are compatible with retention cysts.

IMPRESSION:

1. There is a lesion within the left posterior temporal region, extending into the frontoparietal region as discussed. This has grown when compared with the size given on the prior study mentioned in the PET report, and is suspicious for a primary neoplasm. Due to the rapid change, infection is not entirely excluded, although this appearance would be more typical of neoplasm.

2. There is associated swelling, moderate shift to the right and compression of the left lateral ventricle with the left temporal horn "trapped".

[REDACTED]
Approved By:

[REDACTED]

[REDACTED]

[page 6 of 15]
[REDACTED]

+21

MRI Report [REDACTED]

[REDACTED]

SEX: M

Patient Location: [REDACTED]

Status: I

Accession Number: [REDACTED]

MAGNETIC RESONANCE IMAGING

Physician: [REDACTED]

Requested By: [REDACTED]

Observation Date/Time: [REDACTED] +21

Diagnosis: LT TEMPORAL GBM

History:

POST OP EVALUATION, ?RESIDUAL TUMOR

Dictation Date: [REDACTED] +21

Clinical History: Surgery for left temporal GBM resection.

MRI BRAIN WITH AND WITHOUT CONTRAST:

TECHNIQUE: MRI examination of the brain with 5 mm thick images including sagittal T1-weighted, axial T1, proton density, and T2-weighted images, and coronal FLAIR images. In addition post contrast enhanced axial and coronal T1-weighted images.

+20 COMPARISON: Presurgical MKM study consisting of enhanced T1 axial
dated [REDACTED] and selected MRIs from outside study dated
-29 [REDACTED] and [REDACTED] from [REDACTED] and [REDACTED]
MR respectively. +2

In the left posterior temporal lobe is an operative cavity within which a fluid-fluid level consistent with postoperative blood and fluid. There are multiple linear areas of T1 and T2 low signal consistent with blood and/or surgical material. A mild amount of precontrast T1 hyperintense blood is visualized at the surgical site. On image 11, at the level of the internal cerebral veins, there is a faint additional enhancement along the medial margin of the operative bed. Other than that region, there is no definite additional enhancement other than tiny dots, which most likely represent vessels. Maximal diameter of enhancing material is about 1 cm.

+2

Regarding T2 signal abnormality consistent with edema and/or infiltrating tumor, compared to the [REDACTED] study, the current exam shows progression, in terms of volume and signal intensity itself. This involves the superior and middle temporal lobe, extending to the planum temporale superiorly, around into the insula and medially where it compresses the occipital horn. The dilated left temporal horn is again noted. The amount of compression and mass effect is much greater on the current study than [REDACTED]. The portion of the

+2

[page 7 of 15]
T2 signal abnormalities that has the infiltrative appearance, not quite as bright as edema, extends up to the region of the sensory motor cortex.

The amount of third ventricle midline shift and mass effect on septum pellucidum is slightly improved since the MKM study.

IMPRESSION:

1. Left temporal lobe operative cavity with precontrast blood product. Nearly all of the enhancing tumor appears to have been resected although there is some residual enhancement along the medial border measuring about a centimeter. Note however that early studies document a non-enhancing component as well.

2. Extensive edema and/or infiltrating T2 hyperintensity which have increased significantly since the [REDACTED] and [REDACTED] studies.

+20

-29

+2

3. Since [REDACTED], decreased compression on the left lateral ventricle and occipital horn.

*R

END OF IMPRESSION

Approved By:

[REDACTED]

[REDACTED]

[page 8 of 15]
****FINAL REPORT****

MR BRAIN W&W/O /NO FILMS

Exam Date: [REDACTED] +307

Dept: [REDACTED]

Pt. Status: D

Pt. Location:

Requesting MD: [REDACTED]

MR BRAIN W&W/O CONTRAST /NO FILMS

ACC# [REDACTED] EXAM DATE: [REDACTED]

CNT CODE [REDACTED] +307

Dictation Date: [REDACTED] +307

Clinical History: 51-year-old with left temporal GBM. Assess for tumor progression and compare to prior.

MRI BRAIN WITH AND WITHOUT CONTRAST:

TECHNIQUE: MRI examination of the brain with 5 mm thick images including sagittal T1-weighted, axial T1, proton density, and T2-weighted images, and coronal FLAIR images. In addition post contrast enhanced axial, coronal T1 weighted images and post contrast axial FLAIR.

+157

COMPARISON: Most recent previous outside MRI from [REDACTED] dated [REDACTED] and [REDACTED] MRI dated [REDACTED]. +21

By history, there was an additional outside MRI in [REDACTED] ~+213 but those films are not present in the patient's jacket which includes multiple outside films.

FINDINGS:

There has been significant progression of the enhancing lesion and surrounding T2 hyperintensity in the left posterior temporal-parietal lobe compared with both previous examinations. The lesion is centered at the operative site with thick, irregular, heterogeneous enhancement surrounding the entire operative cavity. In the central portion of the lesion is T1 and T2 shortening, consistent with blood products. The nonenhancing central portion is also consistent with necrosis. In the axial plane on image [REDACTED] of the enhanced T1, it measures (AP x width) 4.2 x 3.5 cm. In the craniocaudal plane, it measures 4.4 cm (image [REDACTED]).

[Continued On Next Page]

[page 9 of 15]
MR BRAIN W&W/O /NO FILMS

Exam Date: [REDACTED] +307

Exam Date: [REDACTED] +307

There has been an increase in the amount of surrounding nonenhancing T2 hyperintensity. Some of this is edema as manifested by gyral swelling. Infiltrating neoplasm may also be present. This component has increased significantly in the interim. On image [REDACTED] of the T2 axial, this measures 9.4 cm AP. It extends from the surface towards the left aspect of the splenium of the corpus callosum, surrounds and mildly compresses the trigone of the left lateral ventricle. T2 signal now extends into white matter tract lateral to the thalamus into posterior aspects of internal and external capsules. Much of the left temporal lobe white matter is now involved.

There is no midline shift or uncus herniation. The thin extraaxial collection at the operative site has significantly decreased since [REDACTED] but only mildly decreased since [REDACTED] ~+157. Nonspecific T2 hyperintense foci in the right frontal white matter are likely chronic.

The rounded bilateral maxillary sinus polyp and mucous retention cysts, right greater than left, are unchanged.

IMPRESSION:

1. Significant progression of irregular, thick enhancing lesion and surrounding nonenhancing T2 hyperintensity, the latter of which may represent edema and/or nonenhancing infiltrative neoplasm. The lesion has progressed since the most recent available previous MRI from [REDACTED] and is consistent with progression of neoplasm.

* 1A +157

* 1A

Interpreting Radiologist

Electronically Signed by:

Trans:

I certify that (1) all services on this form were rendered and are hereby approved for billing. (2) The medical record has been documented for these services, and (3) the rendering of the services and the documentation in the medical record are in accordance with [REDACTED] guidelines.

[page 10 of 15]
MRI Report

+436

SEX: M

Patient Location:

Status: O

Accession Number:

MAGNETIC RESONANCE IMAGING

Physician:

Requested By:

Observation Date/Time:

+436

Diagnosis: LEFT TEMPORAL GBM

History:

STAT READ, SAME DAY DR. APPT

20cc omniscanAPHASIA

? INTERVAL CHANGE

Dictation Date: +437

Clinical History: 52 year old with left temporal GBM.
Aphasia. ?interval change.

MR BRAIN WITH AND WITHOUT CONTRAST

TECHNIQUE: MRI examination of the brain with 5 mm thick images including sagittal T1-weighted, axial T1, proton density, and T2-weighted images, and coronal FLAIR images. In addition post contrast enhanced axial and coronal T1-weighted images.

+366

+338

COMPARISON: MRI dated and

FINDINGS: The trigone of the left lateral ventricle has increased in volume since the previous 2 studies consistent with mild progressive focal volume loss. The blood product in the left posterior temporal surgical bed is unchanged. Compared with the last 2 studies there has been mild progressive improvement in both the thickness of the enhancement in the left temporal parietal operative bed and similarly a mild improvement in the extent of T2 changes surrounding the operative bed. As on the previous studies the T2 changes involve the temporal lobe white matter, posterior left frontal lobe, and occipital lobe white matter. Thin extra-axial collection craniotomy site is stable. There are no lesions. The rest of the examination is unchanged. The soft tissue in the maxillary sinuses and left sphenoid sinus are also stable.

IMPRESSION:

1. A mild progressive improvement in the left temporal parietal heterogeneous enhancement and the surrounding T2 hyperintensity. There has also been a mild increase in the size of the trigone on

[page 11 of 15]
left ventricle indicating focal volume loss. This may represent either improvement in edema or improvement neoplasm.

[page 12 of 15]
RADIOLOGY REPORT

Visit #: [REDACTED]

HAR: [REDACTED]

Patient Information

Age/Sex: 68 year old/Male

Birth Date: [REDACTED]

Signs & Symptoms: left temporal glioblastoma, no treatment since [REDACTED] ~+944; follow-up study to evaluate new enhancing nodule seen on the [REDACTED] study +5226
History: Glioblastoma multiforme (HC code)

Order Information

Exam(s): MR BRAIN W/O CONTRAST [REDACTED]

Accession #: [REDACTED]

Exam Date: [REDACTED]

Ord Provider: [REDACTED]

Final

MR BRAIN W/O CONTRAST - [REDACTED] +5387

~+944

HISTORY: 65 years Male. Left temporal glioblastoma, no treatment since [REDACTED] ~+944; follow-up study to evaluate new enhancing nodule seen on the [REDACTED] study. Assess for interval change; particular attention to new enhancing nodule; please do ASL on the 3T magnet. +5226

TECHNIQUE: Multisequence and multiplanar MRI of the brain was acquired prior to and following intravenous contrast administration per brain tumor protocol with arterial-spin labeled images. The patient received an intravenous injection of 20 ml of Multihance with no adverse reaction.

Imaging was performed at 3.0 Tesla.

+5268, +5226, and +5002

COMPARISON: Brain MRI [REDACTED], [REDACTED], and [REDACTED].

FINDINGS:

Brain and intracranial structures: Further decrease in size of enhancing nodule along the superomedial aspect of the left temporal resection cavity, now measuring 7 x 5 mm (series [REDACTED], image [REDACTED] previously measured 10 x 7 mm. Previously seen faint foci of postcontrast enhancement in the periventricular white matter adjacent to the dilated posterior left lateral ventricle has also decreased in size and conspicuity (series [REDACTED], image [REDACTED]). Remainder foci of postcontrast enhancement, most prominent along the anterior and lateral aspects of the surgical cavity, are unchanged. No areas of hyperperfusion are seen. Local hemosiderin staining again seen. There is stable surrounding T2 hyperintensity. Local volume loss with ex vacuo dilatation of the left atrium is redemonstrated.

Mild cortical thickening and T2 hyperintensity along the left mesial posterior frontal lobe is again seen, slowly progressively increased in conspicuity when dating back to [REDACTED] study. There is no associated postcontrast enhancement. No associated hyperperfusion is seen. +5002

[page 13 of 15]
Remainder of the ventricular system is mildly enlarged, unchanged. Scattered foci of T2 hyperintensity are seen in bilateral white matter, nonspecific. Mild enlargement of the remainder cerebral sulci is unchanged.

There is no hemorrhage or acute infarct.

Skull: Left temporoparietal craniotomy.

Scalp: Postsurgical changes.

Orbits and face (included portions): Normal.

Paranasal sinuses and mastoid air cells (included portions): Mild mucosal thickening in the right maxillary sinus.

IMPRESSION:

1. Further decrease in size of enhancing nodule along the superomedial aspect of the left temporal resection cavity, without associated hyperperfusion, likely representing posttreatment changes.
2. Stable remainder foci of postcontrast enhancement adjacent to the surgical cavity, without associated hyperperfusion, also likely representing posttreatment changes.
3. Interval slight increase in conspicuity of cortical thickening and T2 hyperintensity along the left posterior mesial frontal lobe, slowly progressive when compared to studies dating back to [REDACTED]. No associated postcontrast enhancement or hyperperfusion. Attention on follow-up is recommended. +5002

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Reading Physician: [REDACTED]

[REDACTED]

[page 14 of 15]
RADIOLOGY REPORT

Visit #: [REDACTED]

HAR [REDACTED]

Patient Information

Age/Sex: 68 year old/Male

Signs & Symptoms:

Birth Date: [REDACTED]

History: Glioblastoma (HC code)

Order InformationExam(s): **MR BRAIN W/WO CONTRAST**

Accession #: [REDACTED]

Exam Date [REDACTED]

+5626

Final

MR BRAIN W/WO CONTRAST - [REDACTED] +5626

HISTORY: 66 years Male. Neoplasm: head, CNS, rx monitor or f/u. .

TECHNIQUE: Multisequence and multiplanar MRI of the brain was acquired prior to and following intravenous contrast administration per brain tumor protocol with arterial-spin labeled images. The patient received an intravenous injection of 20 ml of Multihance with no adverse reaction. Imaging was performed at 3.0 Tesla.

COMPARISON: MR brain [REDACTED], MRI brain [REDACTED], MRI brain [REDACTED].
+5599 +5548 +5387

FINDINGS:

Brain and intracranial structures: An enhancing mass within the cingulate gyrus measures 10 mm x 10 mm x 13 mm and is new. This has hyperperfusion on ASL imaging. Surrounding T2 hyperintensity within has increased. Irregular enhancement surrounding the resection cavity is stable from prior. Blood products remain in the cystic component along the resection cavity. Confluent T2 hyperintensity surrounding the resection cavity is unchanged. Unchanged ex vacuo dilatation of the posterior horn of the left lateral ventricle and mildly enlarged right lateral/third ventricles.

There is no hemorrhage or acute infarct.

Skull: Left temporal craniotomy changes.

Scalp: Scarring over the craniotomy.

Orbits and face (included portions): Normal.

Paranasal sinuses and mastoid air cells (included portions): Normal.

[page 15 of 15]
IMPRESSION:

1. An enhancing mass within the left cingulate and superior frontal gyri is new and has hyperperfusion on ASL imaging, suggesting malignant transformation.
2. Stable irregular enhancement surrounding the resection cavity and without elevated perfusion, likely posttreatment change.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file de749737-a24b-4072-a713-f0d054f2a692 (ER0431 ER-B0GH Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).